Somatic mutation profile of tumor specimen MP2PRT-PANZLJ-TMP1-A (aliquot MP2PRT-PANZLJ-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PANZLJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,052 days).
Specimen MP2PRT-PANZLJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f6ff1bb-e4e3-495e-bdd6-cb40149122cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANZLJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANZLJ-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d959a70-28ac-4ae2-b4fa-7cf1d24deb43

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 68/312 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 39/283 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NAP1L3 | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 41/345 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.747); catalogued as COSV100220435; called by muse, mutect2, varscan2
- PDLIM2 | c.496G>A p.A166T (on ENST00000397760; = p.A416T on NM_021630.6) | Missense Mutation (SNP) | VAF 157/549 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs774488635, COSV104380019; called by muse, mutect2, varscan2
- STARD10 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 48/186 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201289203; called by muse, mutect2, varscan2
- ZFHX4 | c.8911C>T p.R2971C | Missense Mutation (SNP) | VAF 133/441 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50500468, COSV50602092; called by muse, mutect2, varscan2
- KAZN | c.58G>A p.V20I | Missense Mutation (SNP) | VAF 63/240 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- EXT1 | c.-546G>A | 5'UTR (SNP) | VAF 164/455 reads (36%) | called by muse, mutect2, varscan2
